Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HO, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HO-01A (Primary Tumor).

Synoptic translated report

Site : Left lung superior lobe

☒ Central ☐ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 8.0 x 7.0 x 7.0 cm

Visceral pleural invasion: ☒ Yes ☐ No ☐ NA

Chest wall invasion : ☐ Yes ☒ No ☐ NA

Histological diagnosis: moderately differentiated squamous cell carcinoma focal keratinizing

Node status : N1 (7/58)

TNM : pT3 (pericardial invasion) pN1 (7/58)

ICD-O-3
Carcinoma, squamous cell
Keratinizing NOS 8671/3
Site: @ Lung, upper lobe
C84.1
JAN 21/13

Pathologist signature:

Date:

Source: NCI Genomic Data Commons file 4a7e7918-daf8-4a2f-9df3-607bd077f452 (TCGA-NC-A5HO.AC6B60E8-F47C-43CD-90C0-3C8DC9778BD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).